Surgical pathology report (de-identified scan), TCGA case TCGA-3H-AB3K, project TCGA-MESO (Mesothelioma), tissue source site MD Anderson Cancer Center, specimen TCGA-3H-AB3K-01A (Primary Tumor).

Accession: [REDACTED]
Specimen Date/Time:

ICD-O-3
Mesothelioma NOS 9050/3
Site: R. Pleura NOS C38.4
J 6/13/14

DIAGNOSIS

(A) LYMPH NODE, STATION 7, BIOPSY:

Negative for tumor.

(B) PLEURA, RIGHT, BIOPSY:

ATYPICAL MESOTHELIAL PROLIFERATION, FAVOR MALIGNANT MESOTHELIOMA.

Immunohistochemical studies show positive staining for calretinin and keratin 5/6 while negative for CEA and MOC-31.

GROSS DESCRIPTION

(A) STATION 7 LYMPH NODE - Received is one possible lymph node (0.4 x 0.4 x 0.3 cm). Entirely submitted in A, for frozen section evaluation.

*FS/DX: ONE LYMPH NODE, NO TUMOR PRESENT.

(B) PLEURAL BIOPSY, RIGHT SIDE - Three fragments of white-tan-yellow soft tissue (0.4 x 0.4 x 0.3 cm each). Entirely submitted in B.

CLINICAL HISTORY

Mesothelioma.

SNOMED CODES

T-29000, M-90503

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file e8c6a5d3-213f-4122-92fc-132cfbc78b6c (TCGA-3H-AB3K.2E921E98-CB9D-4FA5-B67F-A20BB5455CA2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).